Somatic mutation profile of cancer-model specimen HCM-BROD-0035-C49-85M (Adherent Cell Line, passage 7; aliquot HCM-BROD-0035-C49-85M-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0035-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Bone, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 9.8 years (3,585 days).
Specimen HCM-BROD-0035-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0923e8f5-e441-4dfa-8cf6-d93f9e6e2d36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0035-C49-10A (Blood Derived Normal), aliquot HCM-BROD-0035-C49-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7072f625-95c9-46b6-adbd-6c7432460a32

The open-access MAF lists 102 somatic variants for this specimen: 77 protein-altering or splice-affecting, 19 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 19, Frame Shift Del 5, Intron 5, In Frame Del 1, Splice Site 1, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL12A1 | c.1253T>A p.I418K | Missense Mutation (SNP) | VAF 154/296 reads (52%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as rs745309460; called by muse, mutect2, varscan2
- FTMT | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 66/442 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV58420388, COSV58421141; called by muse, mutect2, varscan2
- GREB1 | c.893del p.S298Wfs*3 | Frame Shift Del (DEL) | VAF 208/564 reads (37%) | catalogued as COSV52185107; called by mutect2, pindel, varscan2
- HYDIN | c.9739G>A p.D3247N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.553); catalogued as COSV59275440; called by mutect2, varscan2
- KCP | c.2205C>G p.D735E (on ENST00000620378; = p.D795E on NM_001366122.1) | Missense Mutation (SNP) | VAF 62/442 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV99926387; called by muse, mutect2, varscan2
- LURAP1L | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59985126; called by muse, mutect2
- NBN | c.1064G>T p.S355I | Missense Mutation (SNP) | VAF 117/288 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV55374627; called by mutect2, varscan2
- POTEC | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 96/450 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.993); catalogued as rs756029134, COSV100743746; called by muse, mutect2
- PTGER1 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 53/766 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs779273584; called by muse, mutect2
- SKOR2 | c.2863C>T p.R955* | Nonsense Mutation (SNP) | VAF 32/337 reads (9%) | catalogued as rs1469704775, COSV63336217; called by muse, mutect2
- SPAM1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 93/291 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV56146218, COSV99772626; called by muse, mutect2, varscan2
- TTN | c.56201C>A p.P18734H (on ENST00000591111; = p.P11310H on NM_003319.4) | Missense Mutation (SNP) | VAF 26/371 reads (7%) | PolyPhen probably damaging (0.999); catalogued as COSV60302638; called by muse, mutect2
- USH2A | c.1618del p.Q540Rfs*51 | Frame Shift Del (DEL) | VAF 118/333 reads (35%) | catalogued as CM155344; called by mutect2, pindel, varscan2
- VEPH1 | c.1590G>T p.Q530H | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.179); catalogued as COSV62879205; called by muse, mutect2, varscan2
- ZFR2 | c.1271C>A p.P424H | Missense Mutation (SNP) | VAF 70/1847 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1282268086; called by muse, mutect2
- ABCB10 | c.1996G>T p.A666S | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.07); called by muse, mutect2
- AKAP11 | c.4655T>C p.L1552P | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- AP3D1 | c.1467C>G p.C489W | Missense Mutation (SNP) | VAF 27/329 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ATP2C1 | c.2687A>G p.K896R | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2
- BCL7A | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 88/384 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BNC1 | c.1097T>C p.F366S | Missense Mutation (SNP) | VAF 167/448 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- C1QL1 | c.260dup p.G88Rfs*14 | Frame Shift Ins (INS) | VAF 223/692 reads (32%) | called by mutect2, pindel, varscan2
- CABYR | c.1390T>A p.S464T | Missense Mutation (SNP) | VAF 133/307 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CALB1 | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 17/379 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CASKIN2 | c.1748del p.G583Afs*34 | Frame Shift Del (DEL) | VAF 234/716 reads (33%) | called by mutect2, pindel, varscan2
- CDCP2 | c.1249C>A p.L417I | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); called by muse, mutect2
- COG6 | c.274A>T p.S92C | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); called by muse, mutect2
- COL13A1 | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2
- DACH1 | c.1040T>A p.I347N | Missense Mutation (SNP) | VAF 133/366 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- DDN | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 28/600 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DNAH7 | c.6506C>A p.P2169H | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELMO3 | c.946A>G p.I316V (on ENST00000652269; = p.I263V on NM_024712.5) | Missense Mutation (SNP) | VAF 39/486 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- EP300 | c.1590del p.S531Qfs*7 | Frame Shift Del (DEL) | VAF 60/347 reads (17%) | called by mutect2, pindel, varscan2
- ERFL | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 190/432 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- EXO1 | c.1961T>C p.L654S | Missense Mutation (SNP) | VAF 142/408 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- FREM1 | c.3373G>T p.V1125F | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GABRQ | c.563A>C p.H188P | Missense Mutation (SNP) | VAF 34/357 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- GPR3 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 52/714 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2
- GPR83 | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2
- GSR | c.1539_1544del p.S514_S515del | In Frame Del (DEL) | VAF 162/344 reads (47%) | called by mutect2, pindel, varscan2
- HCCS | c.355del p.V119Ffs*13 | Frame Shift Del (DEL) | VAF 131/391 reads (34%) | called by mutect2, pindel, varscan2
- HDX | c.866C>G p.A289G | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- HERPUD2 | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- IFNA1 | c.173A>T p.D58V | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- INPP5K | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 133/277 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA3 | c.6250C>G p.L2084V (on ENST00000313654 / NM_198129.4; = p.L475V on NM_000227.6) | Missense Mutation (SNP) | VAF 16/305 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LMNB1 | c.1414A>T p.I472F | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- LY96 | c.196A>C p.I66L | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.204); called by muse, mutect2
- MARCHF11 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 13/501 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- MBD5 | c.3920C>A p.T1307N | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.069); called by muse, mutect2
- MIA3 | c.2576A>G p.E859G | Missense Mutation (SNP) | VAF 154/332 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.198); called by muse, mutect2
- MRC2 | c.2690A>G p.D897G | Missense Mutation (SNP) | VAF 66/499 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- NBEAL2 | c.8236A>G p.T2746A | Missense Mutation (SNP) | VAF 175/477 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- NOS2 | c.3153G>T p.K1051N | Missense Mutation (SNP) | VAF 99/333 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NOTCH3 | c.3815C>T p.T1272I | Missense Mutation (SNP) | VAF 41/530 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.223); called by muse, mutect2
- NT5E | c.174G>T p.M58I | Missense Mutation (SNP) | VAF 86/639 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2L2 | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- OR4C5 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 144/339 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNX1 | c.1288A>G p.K430E | Missense Mutation (SNP) | VAF 161/489 reads (33%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRDM5 | c.845A>C p.H282P | Missense Mutation (SNP) | VAF 141/274 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PSMA8 | c.347C>G p.T116S | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RBM20 | c.3451G>A p.G1151R | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIMS2 | c.4560G>T p.Q1520H (on ENST00000666250 / NM_001348490.2; = p.Q1091H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF138 | c.85G>C p.V29L | Missense Mutation (SNP) | VAF 48/558 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2
- RNF17 | c.3892C>A p.P1298T | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RUBCN | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 174/408 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SCN4B | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 34/607 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- SF3B3 | c.3155A>G p.N1052S | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2
- SIRPB2 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 140/338 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC6A4 | c.741C>A p.D247E | Missense Mutation (SNP) | VAF 46/474 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- SPTBN2 | c.772+1G>T p.X258_splice | Splice Site (SNP) | VAF 175/359 reads (49%) | called by muse, mutect2, varscan2
- SRCAP | c.2042A>G p.N681S | Missense Mutation (SNP) | VAF 35/425 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2
- SVOPL | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 125/312 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- SYNE1 | c.21899T>C p.L7300P (on ENST00000367255 / NM_182961.4; = p.L7229P on NM_033071.3) | Missense Mutation (SNP) | VAF 101/163 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TNS3 | c.3472A>G p.K1158E | Missense Mutation (SNP) | VAF 17/397 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- WDR1 | c.960T>A p.S320R (on ENST00000382452; = p.S180R on NM_005112.5) | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2
- ZNF280A | c.1531A>G p.S511G | Missense Mutation (SNP) | VAF 58/600 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); called by muse, mutect2
- ALPK2 | c.1635T>C p.N545= | Silent (SNP) | VAF 73/1882 reads (4%) | catalogued as COSV64494808; called by muse, mutect2
- BMP1 | c.699C>T p.H233= | Silent (SNP) | VAF 173/451 reads (38%) | catalogued as rs1189215947; called by muse, mutect2, varscan2
- CNTN5 | c.2140C>T p.L714= | Silent (SNP) | VAF 28/300 reads (9%) | called by muse, mutect2
- DEFB104B | c.42C>T p.L14= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1447615437; called by mutect2, varscan2
- DENND4C | c.4284T>C p.A1428= (on ENST00000434457 / NM_001330640.2; = p.A1379= on NM_017925.7) | Silent (SNP) | VAF 107/232 reads (46%) | called by muse, mutect2, varscan2
- GALNT7 | c.1083C>A p.L361= | Silent (SNP) | VAF 36/224 reads (16%) | called by muse, mutect2, varscan2
- IGSF9 | c.93C>T p.G31= | Silent (SNP) | VAF 313/656 reads (48%) | called by muse, mutect2, varscan2
- ING4 | c.702G>A p.R234= (on ENST00000396807 / NM_001127582.2; = p.R233= on NM_016162.4) | Silent (SNP) | VAF 50/1337 reads (4%) | catalogued as COSV99975979, COSV99976060; called by muse, mutect2
- LIMK2 | c.996C>A p.I332= | Silent (SNP) | VAF 145/383 reads (38%) | catalogued as COSV59181953; called by muse, mutect2, varscan2
- NOP56 | c.171C>T p.S57= | Silent (SNP) | VAF 557/930 reads (60%) | called by muse, mutect2, varscan2
- OR1L3 | c.858A>G p.P286= | Silent (SNP) | VAF 131/354 reads (37%) | catalogued as rs1412210608; called by muse, mutect2, varscan2
- PLEC | c.12735T>C p.C4245= (on ENST00000322810 / NM_201380.4; = p.C4135= on NM_000445.5) | Silent (SNP) | VAF 237/513 reads (46%) | called by muse, mutect2, varscan2
- SALL3 | c.2832C>A p.A944= | Silent (SNP) | VAF 606/960 reads (63%) | called by muse, mutect2, varscan2
- SCGB1D2 | c.237A>G p.E79= | Silent (SNP) | VAF 73/219 reads (33%) | called by muse, mutect2, varscan2
- SETD2 | c.1839G>A p.G613= | Silent (SNP) | VAF 113/231 reads (49%) | called by muse, mutect2, varscan2
- SH3TC1 | c.1230C>T p.S410= | Silent (SNP) | VAF 125/443 reads (28%) | catalogued as rs376361208; called by muse, varscan2
- SMIM40 | c.42G>C p.L14= | Silent (SNP) | VAF 126/367 reads (34%) | called by muse, mutect2, varscan2
- TDRD15 | c.2250T>C p.Y750= | Silent (SNP) | VAF 101/255 reads (40%) | called by muse, mutect2, varscan2
- UMODL1 | c.3273C>T p.S1091= (on ENST00000408910 / NM_001004416.2; = p.S1219= on NM_173568.3) | Silent (SNP) | VAF 132/328 reads (40%) | catalogued as rs368857995; called by muse, varscan2
- ABI3 | c.*190A>G | 3'UTR (SNP) | VAF 64/400 reads (16%) | called by muse, mutect2, varscan2
- ATP10B | c.470+861G>A | Intron (SNP) | VAF 299/503 reads (59%) | called by muse, mutect2, varscan2
- CD99 | c.475+921T>C | Intron (SNP) | VAF 125/492 reads (25%) | called by muse, mutect2, varscan2
- SLC22A5 | c.394-183A>T | Intron (SNP) | VAF 25/371 reads (7%) | catalogued as rs776539979; called by muse, mutect2
- STEAP1B | c.706-18660A>T | Intron (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2
- WDFY4 | c.1878+28G>T | Intron (SNP) | VAF 48/499 reads (10%) | called by muse, mutect2
